Somatic mutation profile of tumor specimen 1105270 (aliquot 7316UP-547-1105270) from CPTAC case C289419, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105270: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de95eb73-1654-4896-bd9b-15d72edc854f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105213 (Blood Derived Normal), aliquot 7316UP-587-1105213; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/741564e4-9869-4fc1-a1ad-b02fb31debc2

The open-access MAF lists 61 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Intron 5, Frame Shift Del 3, 3'UTR 2, RNA 2, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 62/117 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRF3 | c.1600G>A p.V534M (on ENST00000311519 / NM_001145168.1; = p.V335M on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs753721966; called by muse, mutect2, varscan2
- CACNA1C | c.4900C>T p.R1634C | Missense Mutation (SNP) | VAF 101/268 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100221064; called by muse, mutect2, varscan2
- EGFLAM | c.2010C>A p.H670Q | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59292831; called by muse, mutect2, varscan2
- FAM83B | c.2125A>T p.S709C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60921674; called by muse, mutect2, varscan2
- FGD5 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200418068, COSV53245646; called by muse, mutect2, varscan2
- GPR139 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs773441202, COSV58502871; called by muse, mutect2, varscan2
- HPSE | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1227057746; called by muse, mutect2
- MAGEB3 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 126/146 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV64397343; called by muse, mutect2, varscan2
- MED17 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 111/292 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV52599283; called by muse, mutect2, varscan2
- MYO1B | c.2977G>A p.V993M (on ENST00000304164; = p.V935M on NM_012223.5) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762023617, COSV58428035; called by muse, mutect2, varscan2
- OR51B6 | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs917484033; called by muse, mutect2, varscan2
- OR51F2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs202173777, COSV59063723; called by muse, mutect2, varscan2
- PTEN | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64289424; called by muse, mutect2, varscan2
- RELN | c.2887G>A p.V963I | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as rs761991712, COSV58996805; called by muse, mutect2, varscan2
- SLC25A20 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 194/575 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs376860154; called by muse, mutect2, varscan2
- SSBP3 | c.853G>A p.A285T (on ENST00000371320 / NM_145716.4; = p.A265T on NM_018070.5) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs1018009964, COSV58890055; called by muse, mutect2, varscan2
- TEKT3 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 130/329 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763214298, COSV58629446; called by muse, mutect2, varscan2
- ZC3H13 | c.4712A>G p.N1571S (on ENST00000242848 / NM_001330565.2; = p.N1572S on NM_001076788.2 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1374656138; called by muse, mutect2, varscan2
- AHNAK | c.13037A>T p.E4346V | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- ARHGAP25 | c.1392G>C p.E464D (on ENST00000409202 / NM_001007231.3; = p.E456D on NM_014882.3) | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARHGAP25 | c.1647G>C p.E549D (on ENST00000409202 / NM_001007231.3; = p.E541D on NM_014882.3) | Missense Mutation (SNP) | VAF 102/237 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DYSF | c.4699T>C p.F1567L | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.335); called by muse, mutect2
- EIF4H | c.40A>G p.S14G | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LAMA3 | c.9342del p.K3115Nfs*14 (on ENST00000313654 / NM_198129.4; = p.K1506Nfs*14 on NM_000227.6) | Frame Shift Del (DEL) | VAF 170/539 reads (32%) | called by mutect2, pindel, varscan2
- NEBL | c.1791_1794del p.E598Wfs*7 | Frame Shift Del (DEL) | VAF 85/166 reads (51%) | called by pindel, varscan2
- NFE2 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 231/595 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4A16 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PDCD6 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 97/307 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCSH | c.1566A>C p.E522D | Missense Mutation (SNP) | VAF 146/356 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRMT7 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RSBN1 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SH3BP5L | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 153/290 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAG2 | c.446_449del p.T149Kfs*33 | Frame Shift Del (DEL) | VAF 20/32 reads (63%) | called by mutect2, pindel, varscan2
- TTN | c.76889A>T p.D25630V (on ENST00000591111; = p.D18206V on NM_003319.4) | Missense Mutation (SNP) | VAF 198/494 reads (40%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZMYM6 | c.1379A>G p.D460G | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ATF7IP | c.2934T>C p.A978= | Silent (SNP) | VAF 61/170 reads (36%) | called by muse, mutect2, varscan2
- CLTB | c.312C>G p.R104= | Silent (SNP) | VAF 94/320 reads (29%) | called by muse, mutect2, varscan2
- DENND2C | c.1299T>A p.T433= (on ENST00000393274 / NM_001256404.2; = p.T376= on NM_198459.4) | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- FCHO1 | c.285C>T p.L95= | Silent (SNP) | VAF 84/260 reads (32%) | catalogued as COSV99406523; called by muse, mutect2, varscan2
- HTR1E | c.435C>T p.T145= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs1381760056, COSV59506510; called by muse, mutect2, varscan2
- LCT | c.3135C>T p.Y1045= | Silent (SNP) | VAF 153/474 reads (32%) | catalogued as rs754582267, COSV51555493; called by muse, mutect2, varscan2
- METTL14 | c.1272C>G p.G424= | Silent (SNP) | VAF 91/279 reads (33%) | called by muse, mutect2, varscan2
- OR2Y1 | c.63G>A p.P21= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as rs749891000, COSV57137855; called by muse, mutect2, varscan2
- PPP1R12A | c.339A>G p.A113= | Silent (SNP) | VAF 46/213 reads (22%) | catalogued as rs989012029; called by muse, mutect2, varscan2
- SLC25A44 | c.669C>T p.V223= | Silent (SNP) | VAF 124/259 reads (48%) | called by muse, mutect2, varscan2
- SLC6A13 | c.966C>T p.S322= | Silent (SNP) | VAF 80/203 reads (39%) | catalogued as rs149831603; called by muse, mutect2, varscan2
- TRAV22 | c.258G>A p.T86= | Silent (SNP) | VAF 79/101 reads (78%) | called by muse, mutect2, varscan2
- YME1L1 | c.2283T>A p.I761= (on ENST00000326799 / NM_139312.3; = p.I704= on NM_014263.4) | Silent (SNP) | VAF 63/88 reads (72%) | catalogued as COSV58761380; called by muse, mutect2, varscan2
- AC004080.3 | c.11-4437C>T | Intron (SNP) | VAF 146/534 reads (27%) | called by muse, mutect2, varscan2
- AC021218.1 | n.991T>C | RNA (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2
- AC132217.2 | c.*46+1140C>T | Intron (SNP) | VAF 83/215 reads (39%) | called by muse, mutect2, varscan2
- COL2A1 | c.1942-45G>T | Intron (SNP) | VAF 176/382 reads (46%) | called by muse, mutect2, varscan2
- DPAGT1 | c.1161+30G>A | Intron (SNP) | VAF 176/484 reads (36%) | catalogued as rs777584035, COSV99597773; called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736022 G>T | 5'Flank (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- GPAA1 | c.-66C>T | 5'UTR (SNP) | VAF 40/92 reads (43%) | catalogued as rs942261798; called by muse, mutect2, varscan2
- PDCD6 | c.163+68T>C | Intron (SNP) | VAF 55/177 reads (31%) | called by muse, mutect2, varscan2
- PECR | c.*19C>T | 3'UTR (SNP) | VAF 129/449 reads (29%) | called by muse, mutect2, varscan2
- RNF5P1 | n.52C>T | RNA (SNP) | VAF 95/213 reads (45%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.-38G>A | 5'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as rs1248196134; called by muse, mutect2, varscan2
- TAF10 | c.*1424G>T | 3'UTR (SNP) | VAF 25/768 reads (3%) | called by muse, mutect2
